Surgical pathology report (de-identified scan), TCGA case TCGA-D1-A101, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site Mayo Clinic, specimen TCGA-D1-A101-01A (Primary Tumor).

[page 1 of 2]
100-0-3
Adenocarcinoma, endometrioid, NOS 8380/3
Site Code: Endometrium C54.1 1/17/11
fw

DIAGNOSIS:

A.Uterus, bilateral ovaries and fallopian tubes,
hysterectomy
and bilateral salpingo-oophorectomy:
FIGO grade II (of III) endometrial adenocarcinoma,
endometrioid type
with squamous and mucinous metaplasia, is identified
forming a
polypoid mass (4.0 x 3.0 x 1.0 cm), located in the fundus.
The
tumor invades 0.2 cm into the myometrium (total wall
thickness 1.5
cm). The tumor does not involve the endocervix.
Lymphovascular
space invasion is not identified. The margins are
negative for
tumor. Multiple (3) intramural leiomyomata (ranging in
size from
0.2 cm to 1.5 cm in greatest dimension) are identified. A
benign
endometrial polyp (2.5 x 1.7 x 0.6 cm) is also identified.
The
bilateral ovaries and fallopian tubes are not involved.
[AJCC pT1b
NX Mx]

This final pathology report is based on the
gross/macrosopic
examination and the frozen section histologic evaluation
of the
specimen(s). Hematoxylin and Eosin (H&E) permanent
sections are
reviewed to confirm these findings. Any substantive
changes
identified on permanent section review will be reflected
in a
revised report.

GROSS DESCRIPTION:

A.Received fresh labeled "uterus, right and left fallopian
tubes and ovaries" is a 110 gram uterus with attached
bilateral

[page 2 of 2]
tubes and ovaries and an unremarkable unremarkable cervix.
The
uterine serosa is smooth. There is a 4.0 x 3.0 x 1.0 cm
mass in the
fundus of the endometrial cavity which grossly appears to
invade 0.2
cm into the 1.5 cm thick myometrium. A separate
endometrial polyp
(2.5 x 1.7 x 0.6 cm) is also noted. There are multiple
(3) multiple
intramural leiomyomas ranging from 0.2 cm to 1.5 cm. There
is a 3.0
x 1.2 x 0.7 cm right ovary with a ragged outer surface and
a solid
cut surface with a 7.7 x 0.5 cm right fallopian tube.
There is a
2.5 x 1.5 x 0.7 cm left ovary with a ragged outer surface
and a
solid cut surface with a 7.2 x 0.3 left fallopian tube.
Representative sections submitted.

BLOCK SUMMARY:

Part A: Uterus, right and left fallopian tubes and
ovaries

- 1 Endometrium 1
- 2 Endometrium 2
- 3 Endometrium 3
- 4 Endometrium 4
- 5 Endometrial polyp 1
- 6 Endometrial polyp 2
- 7 Leiomyoma
- 8 Cervix 3:00
- 9 Cervix 6:00
- 10 Endomyometrium
- 11 Rt ovary/tube
- 12 Lt ovary/tube

Source: NCI Genomic Data Commons file 57b5994f-5f41-4303-9042-2f09bae60d82 (TCGA-D1-A101.2D6287C8-9C22-4046-8F14-3886DDE62695.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).